Gene-level copy-number profile of tumor specimen C3N-03228-03 from CPTAC case C3N-03228, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 31.2 years (11,393 days).
Specimen C3N-03228-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c867e0b-82db-4610-adc0-6bffe48fa6f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03228-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/da6e95b1-9110-480c-89d3-061e25bbb1af

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,019; copy number 2: 9,750; copy number 3: 11,610; copy number 4: 29,475; copy number 5: 4,782; copy number 6: 902; copy number 7: 1,336; copy number 8: 16; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:30,517,616–30,580,182, 5 genes: HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2.
- chr11:102,942,995–102,955,732, 1 gene: MMP13.
- chr11:110,049,528–110,050,160, 1 gene: AP001889.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:106,541,673–106,774,279, 5 genes, copy number 9: ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL162574.2.

Autosomal genes at a single copy (total copy number 1): 1,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
